Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3950, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3950-01A (Primary Tumor).

Diagnosis:

Right hemicolectomy preparation with tumor-free resection margins and including an ulcerated, poorly differentiated mucinous adenocarcinoma of the ascending colon, with infiltration of the perimuscular fatty tissue and without evidence of local lymph node metastasis (G3, pT3, L0 V0 R0 pN0 0/17).

Source: NCI Genomic Data Commons file 56f76785-9f47-48a4-9e7b-5b595cef14e5 (TCGA-AA-3950.0154AFCF-E516-4EAF-BDE1-92B7230DDF8A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).